Somatic mutation profile of tumor specimen C3L-05849-02 (aliquot CPT0288830009) from CPTAC case C3L-05849, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 64.3 years (23,490 days).
Specimen C3L-05849-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12586ab4-c562-48c0-a1e4-d78f596612fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05849-31 (Blood Derived Normal), aliquot CPT0297010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/785ed176-c504-429e-939c-e2d84e99085c

The open-access MAF lists 61 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Nonsense Mutation 4, Intron 3, Frame Shift Del 3, Splice Site 1, 5'Flank 1, Splice Region 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK5RAP2 | c.4672C>T p.R1558* | Nonsense Mutation (SNP) | VAF 22/394 reads (6%) | catalogued as rs373278668; ClinVar: pathogenic; called by muse, mutect2
- BRAT1 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777858114, COSV58091826; called by muse, mutect2
- CCDC40 | c.2710G>C p.E904Q | Missense Mutation (SNP) | VAF 22/453 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV66472755; called by muse, mutect2
- CNKSR1 | c.625-1G>A p.X209_splice | Splice Site (SNP) | VAF 30/419 reads (7%) | catalogued as COSV64163939; called by muse, mutect2
- DAO | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140015394; called by muse, mutect2
- DOCK8 | c.3713G>A p.R1238H | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs767874435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELFN2 | c.2053G>A p.G685S | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs763031057; called by muse, mutect2, varscan2
- FAM153A | c.330C>T p.N110= | Splice Region (SNP) | VAF 12/179 reads (7%) | catalogued as rs142185775; called by muse, mutect2
- FBXW7 | c.658C>T p.Q220* (on ENST00000281708 / NM_001349798.2; = p.Q140* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 30/229 reads (13%) | catalogued as COSV55936792, COSV99029508; called by muse, mutect2, varscan2
- GABBR2 | c.1694C>T p.T565M | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1564035609; called by muse, mutect2
- HERC2 | c.11896G>A p.G3966R | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190849970; called by muse, mutect2
- KBTBD4 | c.1074del p.W358* | Frame Shift Del (DEL) | VAF 65/414 reads (16%) | catalogued as COSV100442936; called by mutect2, pindel, varscan2
- LAMC2 | c.2812C>G p.L938V | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.071); catalogued as COSV51453987; called by muse, mutect2
- MC2R | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758727564, COSV59617553, COSV59619547; called by muse, mutect2
- NCK1 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.1); catalogued as rs900756685; called by muse, mutect2, varscan2
- NOS3 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs764271277, COSV52488685; called by muse, mutect2, varscan2
- NSMAF | c.1401G>C p.K467N | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs566534724, COSV50685985; called by muse, mutect2, varscan2
- PCLO | c.9175A>T p.S3059C | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs761293360; called by muse, mutect2, varscan2
- PSG5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 20/341 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61654191; called by muse, mutect2
- SCN8A | c.5597G>A p.R1866Q | Missense Mutation (SNP) | VAF 43/544 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1555231108, COSV100633957; ClinVar: uncertain significance; called by muse, mutect2
- SOAT1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs373499557; called by muse, mutect2
- TSKS | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs770504466; called by muse, mutect2
- ABL2 | c.1381A>G p.T461A (on ENST00000502732 / NM_007314.4; = p.T446A on NM_005158.5) | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2
- APOF | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); called by muse, mutect2
- ARHGAP20 | c.2811_2824del p.S937Rfs*21 | Frame Shift Del (DEL) | VAF 7/80 reads (9%) | called by mutect2, pindel
- ARMC1 | c.848G>T p.*283Lext*55 | Nonstop Mutation (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- BRD4 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CACNA1I | c.297C>A p.Y99* | Nonsense Mutation (SNP) | VAF 18/267 reads (7%) | called by muse, mutect2
- CSNK2A3 | c.904G>T p.D302Y | Missense Mutation (SNP) | VAF 35/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CST7 | c.203T>C p.F68S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DOCK5 | c.2699A>C p.E900A | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- FGR | c.1315T>A p.S439T | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLNB | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 53/448 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GCM1 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 18/302 reads (6%) | called by muse, mutect2
- KMT5A | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MAP1A | c.3361G>A p.G1121S | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2
- MAP6D1 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- NECAB3 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NKTR | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- PIGR | c.149A>C p.H50P | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POP7 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 61/520 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- SLITRK5 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- SOX17 | c.109dup p.S37Kfs*44 | Frame Shift Ins (INS) | VAF 40/436 reads (9%) | called by mutect2, pindel
- SPIC | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.159); called by muse, mutect2
- TBCD | c.3053C>A p.A1018D | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TP53 | c.167_198del p.E56Afs*82 | Frame Shift Del (DEL) | VAF 21/226 reads (9%) | called by mutect2, pindel
- ADRM1 | c.867C>G p.A289= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- CDK5R2 | c.1011C>G p.G337= | Silent (SNP) | VAF 14/228 reads (6%) | catalogued as rs1013451996, COSV56937056; called by muse, mutect2
- GALNT9 | c.495G>A p.S165= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs372597873; called by muse, mutect2
- IRS2 | c.105C>T p.G35= | Silent (SNP) | VAF 21/256 reads (8%) | catalogued as rs781122288; called by muse, mutect2
- NAT8L | c.447C>T p.R149= | Silent (SNP) | VAF 46/403 reads (11%) | called by muse, mutect2, varscan2
- NYX | c.660C>A p.A220= | Silent (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- PCDHGA3 | c.2265C>T p.H755= | Silent (SNP) | VAF 28/364 reads (8%) | catalogued as COSV53927196; called by muse, mutect2
- RANBP2 | c.1710T>C p.L570= | Silent (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2
- SFTPA2 | c.696G>A p.Q232= | Silent (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
- TG | c.3615G>T p.G1205= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV55090784; called by muse, mutect2
- UTS2R | c.1125G>A p.A375= | Silent (SNP) | VAF 49/205 reads (24%) | catalogued as rs1157576926; called by muse, mutect2, varscan2
- DST | c.4296+3872C>A | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- PCBP2 | c.93+43C>T | Intron (SNP) | VAF 7/62 reads (11%) | catalogued as rs776807923; called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863507 C>A | 5'Flank (SNP) | VAF 27/319 reads (8%) | called by muse, mutect2
- SLC6A6 | c.229+57G>C | Intron (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
